Somatic mutation profile of tumor specimen TCGA-CR-7401-01A (aliquot TCGA-CR-7401-01A-11D-2012-08) from TCGA case TCGA-CR-7401, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 64.1 years (23,420 days).
Specimen TCGA-CR-7401-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7700f4f1-5bd1-4230-9ab3-40f7056f93be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7401-10A (Blood Derived Normal), aliquot TCGA-CR-7401-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e92046d6-8d18-4721-8ec5-16638b1e3e4a

The open-access MAF lists 89 somatic variants for this specimen: 58 protein-altering or splice-affecting, 29 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 29, Nonsense Mutation 4, 3'Flank 1, RNA 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1031T>G p.V344G | Missense Mutation (SNP) | VAF 10/58 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1057519941, COSV55876054, COSV55895486, COSV55974473; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.672G>A p.E224= | Splice Region (SNP) | VAF 4/28 reads (14%) | catalogued as rs267605076, CS100446, COSV52678333, COSV52681634, COSV52721244; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- ADAMTS20 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.065); catalogued as COSV101240613; called by muse, mutect2, varscan2
- ADAMTS7 | c.4775G>A p.R1592H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs763966802, COSV101183309; called by mutect2, varscan2
- ALKBH2 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs767138703, COSV99655372, COSV99655499; called by muse, mutect2, varscan2
- ARHGEF2 | c.1747G>C p.E583Q (on ENST00000361247 / NM_001162383.2; = p.E555Q on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100561288; called by muse, mutect2, varscan2
- ASXL3 | c.2123C>G p.S708C | Missense Mutation (SNP) | VAF 38/256 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52461885; called by muse, mutect2, varscan2
- C5AR1 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141160351; called by muse, mutect2, varscan2
- FAT4 | c.5174A>G p.E1725G | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV101272921; called by muse, mutect2
- GZMK | c.71A>T p.N24I | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.129); catalogued as COSV99141037; called by muse, mutect2, varscan2
- H2BC10 | c.344G>A p.G115D | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.96); catalogued as COSV100010394; called by muse, mutect2, varscan2
- IKBKE | c.365G>A p.G122D | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65626826; called by muse, mutect2
- JAKMIP1 | c.1703A>G p.E568G | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV99290990; called by muse, mutect2, varscan2
- KIF14 | c.3283C>T p.Q1095* | Nonsense Mutation (SNP) | VAF 9/85 reads (11%) | catalogued as COSV66260601; called by muse, mutect2, varscan2
- KLHL15 | c.430G>A p.G144S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as rs188398180, COSV100044483; called by muse, mutect2, varscan2
- KRT38 | c.1239C>A p.C413* | Nonsense Mutation (SNP) | VAF 8/63 reads (13%) | catalogued as COSV99878439; called by muse, mutect2, varscan2
- LAMA2 | c.4738G>A p.G1580S | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV101370934; called by muse, mutect2, varscan2
- LAMA3 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV100557794; called by muse, mutect2, varscan2
- MCF2L2 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs772064474, COSV100194178; called by muse, mutect2, varscan2
- MDGA2 | c.2279A>G p.N760S (on ENST00000399232 / NM_001113498.2; = p.N462S on NM_182830.4) | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.03); catalogued as rs1173434445, COSV100638756, COSV62103957; called by muse, mutect2
- MRTFA | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100844443; called by muse, mutect2
- MS4A14 | c.1331A>T p.N444I | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100280776; called by muse, mutect2, varscan2
- MTMR8 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.05); catalogued as COSV100878675; called by muse, mutect2, varscan2
- MYO1G | c.1999G>A p.D667N | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs199839026, COSV51855453; called by mutect2, varscan2
- NID2 | c.3118G>A p.V1040M | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1461741815, COSV53500270; called by muse, mutect2, varscan2
- NLRP1 | c.322C>G p.P108A | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as rs141118572; called by muse, mutect2, varscan2
- OR2T3 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs558628738, COSV62083981; called by muse, mutect2, varscan2
- PATJ | c.1345C>G p.L449V | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV100335187; called by muse, mutect2, varscan2
- PCDHGB1 | c.1870A>C p.T624P | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99548836; called by muse, mutect2, varscan2
- PEX11A | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 67/287 reads (23%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs771174823, COSV55584967; called by muse, mutect2, varscan2
- PIK3C2A | c.3641G>A p.W1214* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV99791370; called by muse, mutect2, varscan2
- PLA2G3 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.212); catalogued as COSV99312157; called by muse, mutect2
- POLR1B | c.2458C>T p.Q820* | Nonsense Mutation (SNP) | VAF 20/130 reads (15%) | catalogued as COSV54497584; called by muse, mutect2, varscan2
- PREX2 | c.3478A>G p.S1160G | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1321308919, COSV99910494; called by muse, mutect2, varscan2
- PRSS12 | c.1738A>G p.I580V | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as rs758974333, COSV99628990; called by muse, mutect2, varscan2
- PTGIS | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.165); catalogued as COSV99721384; called by muse, mutect2, varscan2
- REV3L | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.097); catalogued as rs752852448, COSV62618674; called by muse, mutect2, varscan2
- RIMBP2 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.327); catalogued as rs1209500875, COSV99900818; called by muse, mutect2, varscan2
- RNF31 | c.3109C>T p.R1037C | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.109); catalogued as rs201477229; called by muse, mutect2, varscan2
- SERGEF | c.345G>T p.M115I | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99787954; called by muse, mutect2, varscan2
- SMC1B | c.1757G>A p.R586K | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100663572; called by muse, mutect2
- SP140L | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs747016700, COSV99707074; called by muse, mutect2, varscan2
- SYBU | c.1724G>A p.R575K (on ENST00000276646 / NM_001099754.2; = p.R574K on NM_017786.6) | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99406750; called by muse, mutect2
- TBC1D10C | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.205); catalogued as rs1281525002, COSV100408401; called by muse, mutect2, varscan2
- TCAIM | c.108G>C p.L36F | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100703451; called by muse, mutect2, varscan2
- TMEM115 | c.923A>G p.D308G | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as COSV99223310; called by muse, mutect2, varscan2
- TMEM145 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs1346437365, COSV100004186; called by muse, mutect2, varscan2
- TNS1 | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as rs751369945, COSV50725889; called by muse, mutect2, varscan2
- TRPC6 | c.2668G>C p.D890H | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100723796; called by muse, mutect2, varscan2
- TSPYL5 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.255); catalogued as rs779895860, COSV100439174; called by mutect2, varscan2
- USP17L2 | c.97C>A p.Q33K | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0.191); catalogued as COSV100414793; called by mutect2, varscan2
- ZNF10 | c.785A>T p.E262V | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV99940226; called by muse, mutect2
- ZNF471 | c.1868G>C p.G623A | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100340930; called by muse, mutect2, varscan2
- ZNF548 | c.1520C>G p.S507C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.187); catalogued as rs746298185, COSV100278323; called by muse, mutect2, varscan2
- ZNF649 | c.1302G>T p.E434D | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV100031363; called by muse, mutect2, varscan2
- ZNF804B | c.1655A>G p.Y552C | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs1343377193, COSV100306756; called by muse, mutect2
- ACACA | c.3152G>A p.R1051Q | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- ATP6V0D1 | c.944_946del p.F315del | In Frame Del (DEL) | VAF 13/101 reads (13%) | called by pindel, varscan2
- CCDC85A | c.984C>T p.H328= | Silent (SNP) | VAF 12/138 reads (9%) | catalogued as rs766118772, COSV68152936; called by muse, mutect2
- DPYSL5 | c.138C>T p.G46= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs761018813, COSV56511644; called by muse, mutect2, varscan2
- EPHA3 | c.2127T>C p.S709= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV100349496; called by muse, mutect2, varscan2
- EPHA6 | c.507A>G p.V169= | Silent (SNP) | VAF 19/156 reads (12%) | catalogued as COSV101066022, COSV67595678; called by muse, mutect2, varscan2
- ERBB4 | c.2055C>T p.A685= | Silent (SNP) | VAF 15/100 reads (15%) | catalogued as COSV99635230; called by muse, mutect2, varscan2
- FAT4 | c.14610C>A p.P4870= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV100630500; called by muse, mutect2
- FSTL4 | c.444G>A p.L148= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV99534022; called by muse, mutect2, varscan2
- GUCY1A2 | c.972T>C p.C324= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV99977420; called by muse, mutect2, varscan2
- IGKV6D-41 | c.93C>G p.L31= | Silent (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- LRRC6 | c.1059C>T p.V353= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs1381675903, COSV99138766; called by muse, mutect2, varscan2
- LYST | c.5346C>T p.S1782= | Silent (SNP) | VAF 22/115 reads (19%) | catalogued as COSV101090451; called by muse, mutect2, varscan2
- MAGED1 | c.1374G>A p.Q458= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV100431897, COSV100431920; called by muse, mutect2, varscan2
- MAPK14 | c.204C>T p.T68= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV100005253; called by muse, mutect2, varscan2
- MUC16 | c.20664G>T p.A6888= | Silent (SNP) | VAF 37/226 reads (16%) | catalogued as COSV101202071; called by muse, mutect2, varscan2
- NAGS | c.855G>A p.L285= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV99518057; called by muse, mutect2, varscan2
- OPCML | c.228C>T p.Y76= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as rs142071206; called by mutect2, varscan2
- PIK3CG | c.726C>T p.G242= | Silent (SNP) | VAF 19/129 reads (15%) | catalogued as rs779094560, COSV100783265; called by muse, mutect2, varscan2
- PLEKHA5 | c.597C>G p.L199= | Silent (SNP) | VAF 24/162 reads (15%) | catalogued as COSV100164886, COSV54697648; called by muse, mutect2, varscan2
- POMP | c.411A>G p.K137= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV101076940; called by muse, mutect2, varscan2
- PREX1 | c.1482C>T p.F494= | Silent (SNP) | VAF 18/126 reads (14%) | catalogued as COSV100906889; called by muse, mutect2, varscan2
- PTPRD | c.2241T>C p.Y747= | Silent (SNP) | VAF 17/111 reads (15%) | catalogued as COSV100647564; called by muse, mutect2, varscan2
- SLC4A4 | c.504A>T p.G168= (on ENST00000264485 / NM_001098484.3; = p.G124= on NM_003759.4) | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV99143264; called by muse, mutect2, varscan2
- SRCAP | c.8791C>T p.L2931= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as COSV99351594; called by muse, mutect2, varscan2
- TAAR6 | c.144T>C p.F48= | Silent (SNP) | VAF 19/138 reads (14%) | catalogued as COSV99256940; called by muse, mutect2, varscan2
- TRPC4 | c.2415G>A p.P805= (on ENST00000379705 / NM_016179.4; = p.P810= on NM_003306.3) | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as rs1386697561, COSV58999429, COSV59001099; called by muse, mutect2, varscan2
- TSHZ3 | c.1650C>T p.I550= | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as COSV99553053; called by muse, mutect2
- USP20 | c.2262C>T p.V754= | Silent (SNP) | VAF 29/95 reads (31%) | catalogued as COSV100204867; called by muse, mutect2, varscan2
- ZMYM6 | c.388C>T p.L130= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV100451699; called by muse, mutect2, varscan2
- ZNF761 | c.432T>C p.F144= | Silent (SNP) | VAF 18/133 reads (14%) | catalogued as COSV100483511; called by muse, mutect2, varscan2
- C2orf83 | n.324G>A | RNA (SNP) | VAF 19/86 reads (22%) | catalogued as COSV100018271; called by muse, mutect2, varscan2
- TMEM167B | chr1:109100235 C>T | 3'Flank (SNP) | VAF 6/26 reads (23%) | catalogued as rs1157794972; called by muse, mutect2, varscan2
